Somatic mutation profile of tumor specimen ALCH-AEOW-TTP1-A (aliquot ALCH-AEOW-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEOW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.5 years (22,092 days).
Specimen ALCH-AEOW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75acbac6-ea9f-4202-b090-bbfac199c729.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEOW-NB1-A (Blood Derived Normal), aliquot ALCH-AEOW-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0b9b402-be51-404d-b693-e860e2348b43

The open-access MAF lists 226 somatic variants for this specimen: 142 protein-altering or splice-affecting, 60 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 60, Nonsense Mutation 11, Intron 9, RNA 5, 3'UTR 5, Splice Site 4, 5'UTR 4, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.6629C>T p.S2210F (on ENST00000272895 / NM_173076.3; = p.S1892F on NM_015657.3) | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV55961716; called by muse, mutect2
- ABL1 | c.1589C>A p.T530N | Missense Mutation (SNP) | VAF 39/698 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV59328916; called by muse, mutect2
- ACAN | c.6607T>C p.S2203P | Missense Mutation (SNP) | VAF 56/573 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV100719184; called by muse, mutect2
- ACTA1 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 187/944 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.75); catalogued as COSV64203090, COSV64203524; called by muse, mutect2, varscan2
- ADAM29 | c.1304C>A p.S435Y | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63667058; called by muse, mutect2
- ADAMTS19 | c.2102G>A p.W701* | Nonsense Mutation (SNP) | VAF 26/192 reads (14%) | catalogued as COSV50732807; called by muse, mutect2, varscan2
- APC2 | c.5890G>C p.G1964R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs1183124815; called by muse, mutect2
- CCT8L2 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 22/863 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as COSV63461767, COSV63463898; called by muse, mutect2
- CLEC1A | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59532586; called by muse, mutect2
- CLRN1 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 44/516 reads (9%) | catalogued as COSV58992457, COSV58995663; called by muse, mutect2
- CLVS2 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); catalogued as COSV51561523, COSV51566135; called by muse, mutect2
- CNDP2 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1033113132, COSV60839348, COSV60840286; called by muse, mutect2
- DAAM2 | c.1954-1G>T p.X652_splice | Splice Site (SNP) | VAF 36/254 reads (14%) | catalogued as COSV51311419; called by muse, mutect2, varscan2
- DIP2C | c.4465G>C p.D1489H | Missense Mutation (SNP) | VAF 78/484 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as COSV55155129; called by muse, mutect2, varscan2
- DYRK4 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50538195; called by muse, mutect2
- FAM135B | c.2912G>T p.G971V | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.082); catalogued as COSV52729001; called by muse, mutect2, varscan2
- FAM161A | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 28/521 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101295708; called by muse, mutect2
- GCKR | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 26/863 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.181); catalogued as COSV53110955; called by muse, mutect2
- GGA3 | c.613G>A p.E205K (on ENST00000537686 / NM_138619.4; = p.E172K on NM_014001.5) | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs749990995; called by muse, mutect2
- INO80D | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 17/381 reads (4%) | catalogued as COSV68958245; called by muse, mutect2
- ITGA2B | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 51/788 reads (6%) | catalogued as COSV52232695; called by muse, mutect2
- ITGAL | c.1411C>A p.Q471K | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as COSV63324419; called by muse, mutect2
- KSR2 | c.1486C>G p.Q496E | Missense Mutation (SNP) | VAF 19/513 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.135); catalogued as COSV56675851; called by muse, mutect2
- LRRTM4 | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 22/427 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs1210695407, COSV69142079; called by muse, mutect2
- MAGEB4 | c.592A>T p.N198Y | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66776438; called by muse, mutect2, varscan2
- MAGEC2 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs760470461; called by muse, mutect2, varscan2
- MRC1 | c.3641G>C p.R1214T | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.213); catalogued as rs1164887425; called by muse, mutect2
- MYH1 | c.5533C>T p.R1845C | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1039075314, COSV56843263; called by muse, mutect2
- NBEAL2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs1215864966, COSV52753608; called by muse, mutect2
- NFATC1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53701590; called by muse, mutect2
- NFATC4 | c.1742C>G p.S581* | Nonsense Mutation (SNP) | VAF 11/135 reads (8%) | catalogued as COSV51613529; called by muse, mutect2
- NLRP13 | c.2545C>T p.R849W | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs908899358; called by muse, mutect2
- NOL4 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 20/395 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52348516; called by muse, mutect2
- NOTO | c.460A>G p.R154G | Missense Mutation (SNP) | VAF 24/530 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV68260778; called by muse, mutect2
- NRXN1 | c.2671T>A p.C891S | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as COSV58484588; called by muse, mutect2
- NUDT16 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.554); catalogued as rs1230878972, COSV63248141, COSV63248711; called by muse, mutect2
- OR52J3 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473023004; called by muse, mutect2
- PBRM1 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 17/232 reads (7%) | catalogued as COSV56303013; called by muse, mutect2
- PCDHB7 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 36/502 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50773162; called by muse, mutect2
- PHLDB1 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 85/538 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs374599436; called by muse, mutect2, varscan2
- RASA1 | c.2804A>T p.K935I | Missense Mutation (SNP) | VAF 30/462 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57201501; called by muse, mutect2
- RELN | c.7916G>T p.R2639L | Missense Mutation (SNP) | VAF 52/558 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs369735904; called by muse, mutect2
- RTEL1 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs1219409480; called by muse, mutect2
- RYR1 | c.8005G>C p.E2669Q | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62104483; called by muse, mutect2
- SPATA31D1 | c.2332G>C p.E778Q | Missense Mutation (SNP) | VAF 22/526 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.696); catalogued as rs1238651321, COSV61194266, COSV61200258; called by muse, mutect2
- THRB | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867926730, COSV54979328; called by muse, mutect2
- THSD7B | c.398C>G p.T133R | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.921); catalogued as COSV55683996; called by muse, mutect2
- UMOD | c.701C>A p.T234K | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as rs1426900885, COSV56773218; called by muse, mutect2, varscan2
- WDR17 | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54583831; called by muse, mutect2
- WDR27 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 22/664 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1239861628, COSV61207107; called by muse, mutect2
- ZFR2 | c.1106C>A p.P369H | Missense Mutation (SNP) | VAF 23/347 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99507579; called by muse, mutect2
- ZNF117 | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as rs1300799400; called by muse, mutect2
- ZNF366 | c.845C>A p.A282E | Missense Mutation (SNP) | VAF 43/490 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV59214874; called by muse, mutect2
- ZNF407 | c.809G>C p.R270P | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV55262064, COSV99995000; called by muse, mutect2
- ABCA13 | c.4298C>G p.S1433C | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- ADAM15 | c.2176T>A p.C726S | Missense Mutation (SNP) | VAF 64/291 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM23 | c.1845G>T p.W615C | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY2 | c.2470-1G>C p.X824_splice | Splice Site (SNP) | VAF 79/690 reads (11%) | called by muse, varscan2
- ANKRD49 | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 25/531 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); called by muse, mutect2
- AP3S2 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2
- ATP10A | c.1991C>A p.A664D | Missense Mutation (SNP) | VAF 17/313 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.071); called by muse, mutect2
- ATP5F1D | c.13G>C p.A5P | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.077); called by muse, mutect2
- C11orf80 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CACNA1E | c.2578G>A p.G860R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CHRM3 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 96/456 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- CLCN2 | c.2503-4C>A | Splice Region (SNP) | VAF 68/916 reads (7%) | called by muse, mutect2
- CNGB3 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 49/398 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- COL22A1 | c.133A>C p.T45P | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- CPQ | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- DCHS1 | c.7432C>A p.H2478N | Missense Mutation (SNP) | VAF 49/585 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2
- DNMT1 | c.3756C>T p.L1252= | Splice Region (SNP) | VAF 28/499 reads (6%) | called by muse, mutect2
- DOP1B | c.2517G>C p.K839N | Missense Mutation (SNP) | VAF 78/782 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.196); called by muse, varscan2
- DSCAML1 | c.1625T>C p.V542A (on ENST00000321322; = p.V482A on NM_020693.4) | Missense Mutation (SNP) | VAF 44/785 reads (6%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAM20C | c.455C>G p.P152R | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FAM83D | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- FAM91A1 | c.2225G>A p.R742K | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, mutect2
- FREM2 | c.4357G>C p.D1453H | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GOLGA6L6 | c.335A>T p.E112V | Missense Mutation (SNP) | VAF 49/526 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GPAT2 | c.1868T>C p.I623T | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.286); called by muse, mutect2
- GSN | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 74/972 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- H2AC16 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 46/893 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- HERC2 | c.2572G>T p.G858C | Missense Mutation (SNP) | VAF 38/577 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IFT80 | c.1952C>G p.S651C | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.43); called by muse, mutect2
- IGF1R | c.3972G>T p.K1324N | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- IGFBP1 | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 44/676 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- IGHV1-24 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 46/562 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2
- IL17RB | c.575A>T p.E192V | Missense Mutation (SNP) | VAF 23/399 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2
- INTS5 | c.1218G>T p.L406F | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2
- IQCK | c.778T>A p.F260I | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ITPK1 | c.541A>T p.I181F | Missense Mutation (SNP) | VAF 36/435 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- ITPR1 | c.7585G>A p.E2529K (on ENST00000354582; = p.E2474K on NM_002222.7) | Missense Mutation (SNP) | VAF 17/548 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KCTD9 | c.214+1G>C p.X72_splice | Splice Site (SNP) | VAF 15/277 reads (5%) | called by muse, mutect2
- KIF21A | c.1783G>C p.E595Q (on ENST00000361418 / NM_001378440.1; = p.E582Q on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- LEPR | c.3260A>G p.K1087R | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- LRRC37B | c.2705A>G p.Y902C | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2
- LYST | c.5923-1G>A p.X1975_splice | Splice Site (SNP) | VAF 13/114 reads (11%) | called by muse, varscan2
- MAP3K13 | c.2051G>T p.S684I | Missense Mutation (SNP) | VAF 36/552 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); called by muse, mutect2
- MDM1 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- MDN1 | c.3060G>C p.K1020N | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2
- MID1 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYF5 | c.319A>T p.K107* | Nonsense Mutation (SNP) | VAF 65/902 reads (7%) | called by muse, mutect2
- MYO5A | c.2197A>G p.K733E | Missense Mutation (SNP) | VAF 40/693 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2
- OLFML1 | c.1094C>A p.P365Q | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- OPA1 | c.2937G>C p.K979N (on ENST00000361510 / NM_130837.3; = p.K924N on NM_015560.3) | Missense Mutation (SNP) | VAF 41/707 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OPRPN | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.205); called by muse, mutect2
- OR2M7 | c.761C>A p.A254E | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- OR4D11 | c.652T>G p.Y218D | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5D13 | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR6F1 | c.316T>A p.S106T | Missense Mutation (SNP) | VAF 89/476 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- PHLDB2 | c.1063G>C p.D355H | Missense Mutation (SNP) | VAF 17/497 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2
- PIDD1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2
- PIK3CD | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.074); called by muse, mutect2
- PNPLA6 | c.573G>T p.K191N (on ENST00000414982 / NM_001166111.2; = p.K143N on NM_006702.5) | Missense Mutation (SNP) | VAF 48/873 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPP2R3A | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 9/200 reads (5%) | called by muse, mutect2
- PRKACG | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 35/480 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKCG | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 61/796 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); called by muse, mutect2
- RIF1 | c.4341A>T p.E1447D | Missense Mutation (SNP) | VAF 14/321 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.078); called by muse, mutect2
- RYR2 | c.3571G>A p.A1191T | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SEPTIN9 | c.458C>G p.T153S (on ENST00000427177 / NM_001113491.2; = p.T135S on NM_006640.4) | Missense Mutation (SNP) | VAF 36/723 reads (5%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); called by muse, mutect2
- SERPINB13 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 21/538 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SHROOM3 | c.5494G>C p.D1832H | Missense Mutation (SNP) | VAF 24/474 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SKOR2 | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 67/732 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ST6GALNAC3 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 15/364 reads (4%) | PolyPhen probably damaging (0.979); called by muse, mutect2
- SUPV3L1 | c.2186G>A p.G729E | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D22A | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 31/332 reads (9%) | called by muse, mutect2
- TCTN3 | c.368C>A p.P123Q | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- TEX13C | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 47/423 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TEX13C | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 20/239 reads (8%) | called by muse, mutect2
- TEX36 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 35/361 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- TNKS | c.2503G>T p.G835C | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNN | c.562T>C p.C188R | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TRPM6 | c.317C>A p.T106N | Missense Mutation (SNP) | VAF 42/719 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.066); called by muse, mutect2
- TTN | c.38924T>A p.V12975E (on ENST00000591111; = p.V5551E on NM_003319.4) | Missense Mutation (SNP) | VAF 21/368 reads (6%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- TTPA | c.227G>T p.W76L | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.261); called by muse, mutect2
- UVSSA | c.2115C>G p.N705K | Missense Mutation (SNP) | VAF 41/554 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VPS33B | c.1297A>G p.T433A | Missense Mutation (SNP) | VAF 42/560 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2
- VWDE | c.1397G>T p.W466L | Missense Mutation (SNP) | VAF 50/619 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZFHX2 | c.3877G>T p.E1293* | Nonsense Mutation (SNP) | VAF 13/322 reads (4%) | called by muse, mutect2
- ZNF429 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- ZNF431 | c.1507A>G p.K503E | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- ZNF80 | c.715C>A p.H239N | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZPBP | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 28/558 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2
- AMOTL2 | c.1995C>T p.A665= | Silent (SNP) | VAF 80/1030 reads (8%) | called by muse, mutect2
- ANKLE1 | c.1368G>A p.E456= (on ENST00000394458; = p.E402= on NM_152363.6) | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- ANKRD60 | c.933A>T p.I311= | Silent (SNP) | VAF 44/538 reads (8%) | called by muse, mutect2
- ATP10A | c.1992C>G p.A664= | Silent (SNP) | VAF 18/318 reads (6%) | called by muse, mutect2
- C6orf120 | c.417C>T p.V139= | Silent (SNP) | VAF 48/871 reads (6%) | called by muse, mutect2
- CD72 | c.669C>T p.F223= | Silent (SNP) | VAF 57/256 reads (22%) | called by muse, mutect2, varscan2
- COL22A1 | c.12C>T p.L4= | Silent (SNP) | VAF 22/354 reads (6%) | called by muse, mutect2
- CSPG4 | c.6213C>T p.G2071= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as rs764380200, COSV57890627; called by muse, mutect2, varscan2
- CTNNA3 | c.1335C>A p.V445= | Silent (SNP) | VAF 17/231 reads (7%) | called by muse, mutect2
- DDX54 | c.2238A>G p.E746= | Silent (SNP) | VAF 32/652 reads (5%) | catalogued as rs1219453224; called by muse, mutect2
- DNAJC6 | c.1554C>T p.P518= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- DOCK10 | c.1074T>C p.N358= | Silent (SNP) | VAF 18/278 reads (6%) | called by muse, mutect2
- FRYL | c.4224C>T p.I1408= | Silent (SNP) | VAF 18/224 reads (8%) | catalogued as COSV99976711; called by muse, mutect2
- GTF3C5 | c.1125G>A p.T375= | Silent (SNP) | VAF 23/339 reads (7%) | catalogued as rs749038131; called by muse, mutect2
- HCN1 | c.2361C>T p.S787= | Silent (SNP) | VAF 71/628 reads (11%) | catalogued as rs758609806, COSV57510971; called by muse, mutect2, varscan2
- HEPH | c.2523G>T p.V841= (on ENST00000343002; = p.V574= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV100295007; called by muse, mutect2, varscan2
- IL20RA | c.174A>T p.P58= | Silent (SNP) | VAF 27/365 reads (7%) | called by muse, mutect2
- KDM2B | c.1686G>A p.L562= | Silent (SNP) | VAF 31/379 reads (8%) | called by muse, mutect2
- KIAA0586 | c.900A>T p.T300= (on ENST00000619416 / NM_001244190.2; = p.T315= on NM_014749.5) | Silent (SNP) | VAF 11/170 reads (6%) | called by muse, mutect2
- LAMP5 | c.138T>C p.D46= | Silent (SNP) | VAF 38/534 reads (7%) | catalogued as rs984589224, COSV99068658; called by muse, mutect2
- LRRC28 | c.615A>G p.L205= | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as rs781137940, COSV100113796; called by muse, mutect2
- MAST1 | c.1722G>C p.G574= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- MS4A18 | c.493C>T p.L165= (on ENST00000398983; = p.L167= on NM_001354471.1) | Silent (SNP) | VAF 75/572 reads (13%) | called by muse, mutect2, varscan2
- MSTN | c.261C>T p.L87= | Silent (SNP) | VAF 18/278 reads (6%) | called by muse, mutect2
- MYH11 | c.375C>T p.V125= | Silent (SNP) | VAF 64/1518 reads (4%) | called by muse, mutect2
- MYH4 | c.3336C>A p.I1112= | Silent (SNP) | VAF 32/523 reads (6%) | catalogued as COSV55123680; called by muse, mutect2
- NAPRT | c.114C>A p.A38= | Silent (SNP) | VAF 12/201 reads (6%) | called by muse, mutect2
- NOTCH1 | c.3813C>T p.C1271= | Silent (SNP) | VAF 54/706 reads (8%) | catalogued as rs1471864651, COSV53056413; called by muse, mutect2
- NOVA2 | c.318C>A p.I106= | Silent (SNP) | VAF 56/670 reads (8%) | called by muse, mutect2
- NPFFR2 | c.69G>T p.P23= | Silent (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2
- NPY1R | c.492C>A p.V164= | Silent (SNP) | VAF 24/252 reads (10%) | called by muse, mutect2
- NR1H4 | c.1065G>A p.P355= (on ENST00000551379 / NM_001206993.2; = p.P341= on NM_005123.4) | Silent (SNP) | VAF 31/428 reads (7%) | catalogued as rs569479207, COSV51857715; called by muse, mutect2
- NRROS | c.1302C>T p.S434= | Silent (SNP) | VAF 52/889 reads (6%) | called by muse, mutect2
- NRXN3 | c.1413C>A p.I471= (on ENST00000335750 / NM_001330195.2; = p.I98= on NM_004796.6) | Silent (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2
- OR13C5 | c.309C>T p.L103= | Silent (SNP) | VAF 13/401 reads (3%) | called by muse, mutect2
- OR14I1 | c.147C>A p.L49= | Silent (SNP) | VAF 21/173 reads (12%) | called by mutect2, varscan2
- OTOP3 | c.1065C>A p.T355= | Silent (SNP) | VAF 34/706 reads (5%) | called by muse, mutect2
- P2RY4 | c.768C>T p.V256= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as COSV65736839; called by muse, mutect2, varscan2
- PALB2 | c.429G>A p.L143= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- PCDHA11 | c.1107C>T p.A369= | Silent (SNP) | VAF 83/647 reads (13%) | catalogued as rs1430379869, COSV56536961; called by muse, mutect2, varscan2
- PCLO | c.9273T>A p.S3091= | Silent (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- PCNX3 | c.3546C>T p.T1182= | Silent (SNP) | VAF 19/206 reads (9%) | catalogued as rs747768738, COSV100856661; called by muse, mutect2
- PDE3A | c.624G>C p.L208= | Silent (SNP) | VAF 18/196 reads (9%) | called by muse, mutect2
- PIK3CG | c.294G>C p.L98= | Silent (SNP) | VAF 35/525 reads (7%) | called by muse, mutect2
- POGLUT2 | c.111C>T p.P37= | Silent (SNP) | VAF 28/240 reads (12%) | catalogued as rs1477176307; called by muse, mutect2, varscan2
- POLD1 | c.2643G>A p.L881= | Silent (SNP) | VAF 19/339 reads (6%) | catalogued as COSV99569959; called by muse, mutect2
- PRNP | c.357G>T p.G119= | Silent (SNP) | VAF 70/924 reads (8%) | called by muse, mutect2
- PTPN9 | c.1674C>T p.I558= | Silent (SNP) | VAF 14/213 reads (7%) | called by muse, mutect2
- RGS18 | c.142C>T p.L48= | Silent (SNP) | VAF 42/250 reads (17%) | called by muse, mutect2, varscan2
- RNF115 | c.354T>C p.P118= | Silent (SNP) | VAF 69/392 reads (18%) | called by muse, mutect2, varscan2
- SEL1L2 | c.393C>T p.Y131= | Silent (SNP) | VAF 17/305 reads (6%) | called by muse, mutect2
- SLC6A18 | c.876C>A p.I292= | Silent (SNP) | VAF 65/498 reads (13%) | catalogued as rs777019163, COSV57250604; called by muse, mutect2, varscan2
- SPECC1L | c.294C>A p.S98= | Silent (SNP) | VAF 37/427 reads (9%) | called by muse, mutect2
- SPEG | c.5487G>T p.R1829= | Silent (SNP) | VAF 31/456 reads (7%) | called by muse, mutect2
- STXBP1 | c.1365G>C p.T455= | Silent (SNP) | VAF 74/1092 reads (7%) | called by muse, mutect2
- TLL1 | c.384T>A p.V128= | Silent (SNP) | VAF 30/427 reads (7%) | called by muse, mutect2
- TNIK | c.2445G>A p.R815= | Silent (SNP) | VAF 24/335 reads (7%) | called by muse, mutect2
- TSPOAP1 | c.5538G>A p.E1846= | Silent (SNP) | VAF 34/352 reads (10%) | called by muse, mutect2
- VPS50 | c.2244A>T p.P748= | Silent (SNP) | VAF 19/273 reads (7%) | called by muse, mutect2
- ZNF445 | c.1797C>T p.C599= | Silent (SNP) | VAF 24/370 reads (6%) | called by muse, mutect2
- ALG12 | c.*19C>T | 3'UTR (SNP) | VAF 43/365 reads (12%) | catalogued as rs374137636, COSV100427190; called by muse, mutect2, varscan2
- ARL13B | c.*163T>G | 3'UTR (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- BAD | c.*10C>T | 3'UTR (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+38833T>G | Intron (SNP) | VAF 56/345 reads (16%) | called by muse, mutect2, varscan2
- BTBD16 | c.-28C>T | 5'UTR (SNP) | VAF 42/330 reads (13%) | called by muse, mutect2, varscan2
- CEP85L | c.-8C>A | 5'UTR (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- COL1A1 | c.2397+61C>T | Intron (SNP) | VAF 13/250 reads (5%) | called by muse, mutect2
- CPLX4 | c.*11G>T | 3'UTR (SNP) | VAF 14/285 reads (5%) | catalogued as COSV100231307; called by muse, mutect2
- DAO | chr12:108879991 G>A | 5'Flank (SNP) | VAF 22/321 reads (7%) | called by muse, mutect2
- DPF3 | c.32+14235G>T | Intron (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- HSP90AA4P | n.2077C>T | RNA (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- LINC01159 | n.157C>T | RNA (SNP) | VAF 34/726 reads (5%) | catalogued as rs980189384; called by muse, mutect2
- LMF1 | c.*515C>T | 3'UTR (SNP) | VAF 27/247 reads (11%) | catalogued as rs551045227; called by muse, mutect2, varscan2
- OCIAD1 | c.58+18A>G | Intron (SNP) | VAF 11/217 reads (5%) | called by muse, mutect2
- OFCC1 | n.2220G>A | RNA (SNP) | VAF 21/180 reads (12%) | called by muse, mutect2, varscan2
- OR5P1P | n.750G>T | RNA (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- PRRC2C | c.8199+927G>T | Intron (SNP) | VAF 73/459 reads (16%) | called by muse, mutect2, varscan2
- RBM14 | c.337+1450C>T | Intron (SNP) | VAF 26/292 reads (9%) | called by muse, mutect2
- RCOR2 | c.1258-45G>A | Intron (SNP) | VAF 37/353 reads (10%) | called by muse, mutect2, varscan2
- SAMSN1 | c.-6G>T | 5'UTR (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- SEPTIN9 | c.1043-9T>G | Intron (SNP) | VAF 37/519 reads (7%) | called by muse, mutect2
- SSUH2 | c.-3-544C>T | Intron (SNP) | VAF 52/857 reads (6%) | called by muse, mutect2
- TRBV23OR9-2 | n.227A>T | RNA (SNP) | VAF 21/355 reads (6%) | called by muse, mutect2
- ZNF727 | c.-27G>A | 5'UTR (SNP) | VAF 42/678 reads (6%) | called by muse, mutect2
